Somatic mutation profile of tumor specimen C3N-02279-01 (aliquot CPT0163790006) from CPTAC case C3N-02279, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 59.1 years (21,586 days).
Specimen C3N-02279-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 313d42db-fe20-42c9-83f5-5a457aff30d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02279-31 (Blood Derived Normal), aliquot CPT0163830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f4e69ce-ac4b-4824-b309-9c98692d72f2

The open-access MAF lists 228 somatic variants for this specimen: 155 protein-altering or splice-affecting, 49 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 49, Intron 13, Nonsense Mutation 11, RNA 4, 3'UTR 4, Frame Shift Del 3, Splice Site 3, Translation Start Site 2, Frame Shift Ins 2, Splice Region 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.2050C>T p.Q684* | Nonsense Mutation (SNP) | VAF 116/589 reads (20%) | catalogued as rs387906848, CM117949, COSV56230282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3131A>G p.N1044S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.297); catalogued as rs1064793838, COSV55874598, COSV99835810, COSV99841106; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.4844G>A p.R1615Q | Missense Mutation (SNP) | VAF 140/742 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs1251839800, CM041977, CM065954; called by muse, mutect2, varscan2
- AFF3 | c.1729G>T p.A577S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.313); catalogued as COSV57864249; called by muse, mutect2, varscan2
- ANXA11 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 86/448 reads (19%) | catalogued as rs1405997143, COSV55416567; called by muse, mutect2, varscan2
- APLNR | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 47/446 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.79); catalogued as rs748168275, COSV99951691; called by muse, mutect2, varscan2
- C1orf87 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 51/392 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV64599055; called by muse, mutect2, varscan2
- COL11A2 | c.1462C>T p.P488S (on ENST00000341947 / NM_080680.3; = p.P381S on NM_080679.2) | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1331669965; called by muse, varscan2
- COL8A1 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs745820775, COSV53736414; called by muse, mutect2, varscan2
- DAB2IP | c.2752G>A p.D918N (on ENST00000408936; = p.D890N on NM_032552.3) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs761839130; called by muse, mutect2, varscan2
- DCLK1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 93/407 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55214935; called by muse, mutect2, varscan2
- DCST2 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 67/621 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.559); catalogued as rs370622842, COSV55051664, COSV99792003; called by muse, mutect2, varscan2
- DNAH12 | c.2196A>T p.K732N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs561409532, COSV61058797; called by muse, mutect2
- DSP | c.8480C>G p.S2827C | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.671); catalogued as rs746773800; called by muse, mutect2, varscan2
- E2F1 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs377637237; called by muse, mutect2, varscan2
- EVPL | c.3478G>A p.E1160K | Missense Mutation (SNP) | VAF 69/376 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs763830732, COSV56909883; called by muse, mutect2, varscan2
- EYS | c.4725G>T p.L1575F | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV58195982; called by muse, mutect2
- FAM135B | c.1803C>A p.H601Q | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV52708236; called by muse, mutect2, varscan2
- FAT2 | c.3980C>T p.S1327L | Missense Mutation (SNP) | VAF 41/363 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV55820752; called by muse, mutect2, varscan2
- GALNS | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 123/716 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761043390, COSV51939367; called by muse, mutect2, varscan2
- GOLGA8J | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 40/708 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as rs773896466; called by muse, mutect2
- HCRTR2 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 37/324 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772748267, COSV63795758; called by muse, mutect2, varscan2
- HLA-A | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 44/298 reads (15%) | catalogued as COSV65142704; called by muse, mutect2, varscan2
- KCNA4 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.103); catalogued as rs778734387; called by muse, mutect2, varscan2
- KIF12 | c.1763C>T p.P588L (on ENST00000640217; = p.P450L on NM_138424.1) | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs71503587; called by muse, mutect2, varscan2
- KIR2DL4 | c.313G>C p.D105H (on ENST00000396284; = p.D66H on NM_001080770.2) | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); catalogued as COSV100610483; called by muse, mutect2, varscan2
- KIR3DL3 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 44/288 reads (15%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.646); catalogued as COSV52549064; called by muse, mutect2, varscan2
- L3MBTL2 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 133/795 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs1189851016; called by muse, mutect2, varscan2
- LRRC4B | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.076); catalogued as COSV65350904; called by muse, mutect2, varscan2
- LRRK1 | c.3877C>T p.R1293W | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs367837232; called by muse, mutect2
- MTSS1 | c.222G>C p.E74D | Missense Mutation (SNP) | VAF 54/360 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100275618; called by muse, mutect2, varscan2
- NLRP13 | c.1481T>C p.M494T | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs753964003; called by muse, mutect2, varscan2
- NPHS1 | c.3262C>T p.R1088W | Missense Mutation (SNP) | VAF 71/374 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs746111275, COSV62287797; called by muse, mutect2, varscan2
- OR2T4 | c.526del p.L176Cfs*21 | Frame Shift Del (DEL) | VAF 84/504 reads (17%) | catalogued as COSV63544424; called by mutect2, pindel, varscan2
- OR7A5 | c.656C>G p.S219C | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.33); catalogued as rs1188228197; called by muse, mutect2
- OR8B3 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.404); catalogued as COSV63541916; called by muse, mutect2, varscan2
- PALLD | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs1412102338, COSV99825993; called by muse, mutect2, varscan2
- PANK3 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 63/343 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as rs376150396; called by muse, mutect2, varscan2
- PAX4 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 108/733 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528075802; called by muse, mutect2, varscan2
- PCDH17 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 101/373 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64980710; called by muse, mutect2, varscan2
- PCDHGA2 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 111/694 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.358); catalogued as rs1355486436, COSV53928692; called by muse, mutect2, varscan2
- PCDHGA3 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 42/602 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.166); catalogued as rs762497935; called by muse, mutect2
- PCDHGA7 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV53912777, COSV99545727; called by muse, mutect2
- PCDHGB3 | c.261C>A p.S87R | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV53891745; called by muse, mutect2, varscan2
- PHLDB2 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs780804335, COSV67308399; called by muse, mutect2, varscan2
- PIK3CD | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 123/633 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1405541611; called by muse, mutect2, varscan2
- PLIN1 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 52/462 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); catalogued as rs747856069, COSV100261529; called by muse, mutect2, varscan2
- PMS2 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as rs746889239; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- PRDM9 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 118/719 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57003780; called by muse, mutect2, varscan2
- SCUBE3 | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 32/432 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1313649538; called by muse, mutect2
- SF3B1 | c.2831C>T p.S944F | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59207895; called by muse, varscan2
- SLC7A11 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs373100601, COSV54928067; called by muse, mutect2, varscan2
- SP4 | c.1129C>G p.Q377E | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.585); catalogued as rs1188178089; called by muse, mutect2, varscan2
- SPON1 | c.1032G>C p.Q344H | Missense Mutation (SNP) | VAF 33/381 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.778); catalogued as COSV59970472; called by muse, mutect2
- TEKT4 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs782507268; called by muse, mutect2, varscan2
- TMEM200C | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.53); catalogued as rs368367316; called by muse, mutect2
- TP53 | c.466dup p.R156Pfs*25 | Frame Shift Ins (INS) | VAF 92/336 reads (27%) | catalogued as COSV52974259, COSV53384084; called by pindel, varscan2
- TRABD | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 92/474 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1265075011; called by muse, mutect2, varscan2
- VASH2 | c.451C>T p.R151* (on ENST00000517399 / NM_001301056.2; = p.R86* on NM_001136474.3) | Nonsense Mutation (SNP) | VAF 16/160 reads (10%) | catalogued as rs1221181181; called by muse, mutect2
- VAT1L | c.74C>A p.A25E | Missense Mutation (SNP) | VAF 80/386 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.27); catalogued as rs1342563168; called by muse, mutect2, varscan2
- ZNF135 | c.547G>A p.E183K (on ENST00000313434 / NM_001289401.2; = p.E195K on NM_003436.4) | Missense Mutation (SNP) | VAF 51/333 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.201); catalogued as rs768046446, COSV100536641; called by muse, mutect2, varscan2
- ABCA4 | c.471G>C p.L157F | Missense Mutation (SNP) | VAF 42/388 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ABHD4 | c.23+6T>C | Splice Region (SNP) | VAF 108/600 reads (18%) | called by muse, varscan2
- ABL1 | c.3171_3191del p.E1058_Y1064del | In Frame Del (DEL) | VAF 46/348 reads (13%) | called by mutect2, pindel
- ACAN | c.5C>G p.T2S | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ACAP2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 53/404 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- AL035461.3 | c.2518G>T p.D840Y | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- APOL5 | c.720C>G p.I240M | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2
- ARHGAP39 | c.1518C>A p.S506R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP45 | c.1299del p.S433Rfs*53 | Frame Shift Del (DEL) | VAF 68/466 reads (15%) | called by mutect2, pindel, varscan2
- ARPC3 | c.128A>G p.D43G | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ATP10A | c.4018T>C p.S1340P | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP10D | c.3763C>T p.H1255Y | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BEND2 | c.1220C>G p.S407* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- C7orf31 | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); called by muse, mutect2
- C8A | c.462G>T p.L154F | Missense Mutation (SNP) | VAF 109/645 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CAPN9 | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- CCDC168 | c.10066G>A p.D3356N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- CDK12 | c.3062A>C p.K1021T | Missense Mutation (SNP) | VAF 13/251 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.051); called by muse, mutect2
- CDRT1 | c.948G>C p.K316N | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CELF1 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CENPQ | c.496G>C p.V166L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CES5A | c.96T>A p.Y32* | Nonsense Mutation (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
- CETN2 | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRNB2 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 56/518 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- CLUL1 | c.881C>G p.S294* | Nonsense Mutation (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- COL19A1 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- COL6A5 | c.776A>G p.E259G | Missense Mutation (SNP) | VAF 13/375 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, mutect2
- DBF4B | c.1189+1G>T p.X397_splice | Splice Site (SNP) | VAF 67/314 reads (21%) | called by muse, mutect2, varscan2
- DNAJB4 | c.165del p.S56Vfs*17 | Frame Shift Del (DEL) | VAF 16/158 reads (10%) | called by mutect2, pindel
- DYNC2H1 | c.3517G>T p.V1173F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DYNC2H1 | c.6455C>G p.A2152G | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DZANK1 | c.2212G>C p.E738Q (on ENST00000262547 / NM_001099407.1; = p.E545Q on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.025); called by muse, mutect2
- FAT1 | c.8044dup p.S2682Ffs*11 | Frame Shift Ins (INS) | VAF 24/130 reads (18%) | called by mutect2, pindel, varscan2
- FERMT1 | c.1818C>G p.F606L | Missense Mutation (SNP) | VAF 50/451 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- GALNTL5 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.223); called by mutect2, varscan2
- GDF6 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 155/963 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GNGT2 | c.100A>C p.K34Q | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- HDAC8 | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- HIPK2 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 38/246 reads (15%) | called by muse, mutect2, varscan2
- HIPK3 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HYDIN | c.217C>A p.Q73K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- IGHMBP2 | c.2842G>A p.G948R | Missense Mutation (SNP) | VAF 44/281 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KLHL7 | c.1523G>C p.W508S (on ENST00000339077 / NM_001031710.3; = p.W460S on NM_018846.5) | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LUC7L | c.61+7C>T | Splice Region (SNP) | VAF 45/321 reads (14%) | called by muse, mutect2, varscan2
- MAP3K3 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, varscan2
- MESP2 | c.723C>G p.H241Q | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, mutect2
- MRPS22 | c.754A>G p.I252V (on ENST00000310776 / NM_001363893.1; = p.I253V on NM_020191.4) | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- MYO3B | c.3338G>T p.R1113I | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- MYOM3 | c.278A>C p.E93A | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2
- NFATC2IP | c.1196C>G p.S399* | Nonsense Mutation (SNP) | VAF 56/326 reads (17%) | called by muse, varscan2
- NOTCH1 | c.4873_4875dup p.E1625dup | In Frame Ins (INS) | VAF 57/306 reads (19%) | called by mutect2, varscan2
- OR10H4 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 64/293 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PALLD | c.687G>C p.E229D | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH9 | c.2891T>C p.I964T | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE11A | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 47/301 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PLEKHG4B | c.2394G>T p.R798S (on ENST00000283426; = p.R1154S on NM_052909.5) | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- POLR2D | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.063); called by muse, mutect2
- PRKAG2 | c.1654C>G p.Q552E | Missense Mutation (SNP) | VAF 54/276 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- RAB24 | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 46/518 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- RAD54B | c.2221G>C p.D741H | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- RYR3 | c.11134G>C p.E3712Q (on ENST00000389232; = p.E3713Q on NM_001036.6) | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- SALL1 | c.2140G>T p.V714F | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SALL2 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAP30BP | c.866G>C p.S289T | Missense Mutation (SNP) | VAF 59/350 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SBF2 | c.4465G>C p.E1489Q | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SF3B1 | c.2896C>G p.Q966E | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, varscan2
- SLC13A3 | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.442); called by muse, mutect2
- SLIT3 | c.2571C>G p.N857K | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- SNRK | c.2166G>C p.K722N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOGA3 | c.1928C>T p.S643L | Missense Mutation (SNP) | VAF 56/279 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- SPTA1 | c.3477+1G>T p.X1159_splice | Splice Site (SNP) | VAF 29/168 reads (17%) | called by muse, mutect2, varscan2
- SSC5D | c.4687G>A p.E1563K | Missense Mutation (SNP) | VAF 109/596 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SVIP | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- SYNPO2 | c.3055G>A p.V1019M | Missense Mutation (SNP) | VAF 86/378 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- TAL1 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- TBX22 | c.995C>A p.P332H | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- TMEM131 | c.3195C>G p.I1065M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TMEM191C | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 83/454 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNKS | c.1750-1G>C p.X584_splice | Splice Site (SNP) | VAF 26/112 reads (23%) | called by muse, varscan2
- TOR1AIP2 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- TRPC3 | c.880C>A p.L294M (on ENST00000379645 / NM_001366479.2; = p.L221M on NM_003305.2) | Missense Mutation (SNP) | VAF 103/541 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- U2SURP | c.2487G>C p.K829N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- UGT3A2 | c.353C>A p.A118E | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- UNC80 | c.3980A>G p.D1327G | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- USP48 | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VNN2 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WFDC2 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZFHX3 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF268 | c.2707C>G p.Q903E | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- ZNF404 | c.1556G>A p.G519D | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2
- ZNF679 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF726 | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 63/433 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF749 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 47/254 reads (19%) | called by muse, mutect2, varscan2
- ZNF813 | c.1792C>T p.H598Y | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ANKRD10 | c.711C>T p.A237= | Silent (SNP) | VAF 41/213 reads (19%) | catalogued as rs144207809; called by muse, mutect2, varscan2
- ARPIN | c.30C>G p.L10= | Silent (SNP) | VAF 32/332 reads (10%) | called by muse, mutect2
- BAIAP3 | c.1890G>A p.L630= | Silent (SNP) | VAF 105/527 reads (20%) | catalogued as rs766574340; called by muse, mutect2, varscan2
- CABIN1 | c.5109C>A p.L1703= | Silent (SNP) | VAF 49/259 reads (19%) | called by muse, mutect2, varscan2
- CCDC88C | c.48G>T p.P16= | Silent (SNP) | VAF 56/310 reads (18%) | called by muse, varscan2
- CPXM2 | c.1608G>T p.T536= | Silent (SNP) | VAF 48/241 reads (20%) | catalogued as rs140485162; called by muse, mutect2, varscan2
- DBX2 | c.180C>T p.H60= | Silent (SNP) | VAF 31/274 reads (11%) | catalogued as COSV60337301; called by muse, mutect2, varscan2
- DNAH5 | c.7566G>T p.A2522= | Silent (SNP) | VAF 174/501 reads (35%) | called by muse, mutect2, varscan2
- DYNC1I1 | c.201T>G p.G67= | Silent (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2, varscan2
- E2F1 | c.1182C>T p.L394= | Silent (SNP) | VAF 46/223 reads (21%) | called by muse, mutect2, varscan2
- EEF2KMT | c.144G>T p.R48= | Silent (SNP) | VAF 86/520 reads (17%) | called by muse, mutect2, varscan2
- FAM149A | c.1878C>A p.P626= (on ENST00000356371 / NM_001367768.2; = p.P335= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 78/364 reads (21%) | catalogued as COSV99906314; called by muse, mutect2, varscan2
- FERMT1 | c.1461C>T p.L487= | Silent (SNP) | VAF 85/530 reads (16%) | catalogued as COSV54092927; called by muse, mutect2, varscan2
- FMNL1 | c.1092C>A p.L364= | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- GPAT4 | c.240C>A p.I80= | Silent (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- GUCY1A1 | c.459G>A p.G153= | Silent (SNP) | VAF 41/204 reads (20%) | catalogued as rs770668312; called by muse, mutect2, varscan2
- H2BC3 | c.195C>G p.S65= | Silent (SNP) | VAF 23/348 reads (7%) | called by muse, mutect2
- KCNB2 | c.177G>A p.T59= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs566076958, COSV73049681; called by muse, mutect2, varscan2
- KCNG2 | c.831C>A p.T277= | Silent (SNP) | VAF 50/155 reads (32%) | called by muse, mutect2, varscan2
- LCE2D | c.216C>T p.C72= | Silent (SNP) | VAF 79/435 reads (18%) | catalogued as rs756264813, COSV100909602; called by muse, mutect2, varscan2
- LTB4R2 | c.615G>A p.S205= (on ENST00000528054; = p.S174= on NM_019839.5) | Silent (SNP) | VAF 195/923 reads (21%) | called by muse, mutect2, varscan2
- MESP2 | c.153C>G p.L51= | Silent (SNP) | VAF 69/708 reads (10%) | catalogued as rs1257990941; called by muse, mutect2
- MORC1 | c.567G>C p.V189= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV51728939; called by muse, mutect2, varscan2
- MROH7 | c.714G>C p.G238= | Silent (SNP) | VAF 69/374 reads (18%) | called by muse, mutect2, varscan2
- MYRF | c.2202G>A p.A734= (on ENST00000278836 / NM_001127392.3; = p.A725= on NM_013279.4) | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs146182410; called by muse, mutect2, varscan2
- NBEAL1 | c.4956C>T p.F1652= | Silent (SNP) | VAF 30/201 reads (15%) | catalogued as COSV71375432; called by muse, mutect2, varscan2
- NDUFAF4 | c.321G>A p.K107= | Silent (SNP) | VAF 47/212 reads (22%) | called by muse, mutect2, varscan2
- NEURL2 | c.648C>T p.S216= | Silent (SNP) | VAF 39/507 reads (8%) | called by muse, mutect2
- NOC2L | c.816C>T p.A272= | Silent (SNP) | VAF 68/384 reads (18%) | catalogued as rs767288314; called by muse, mutect2, varscan2
- ODR4 | c.822A>T p.I274= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- OR4D6 | c.675G>A p.L225= | Silent (SNP) | VAF 36/253 reads (14%) | catalogued as COSV55660024; called by muse, mutect2, varscan2
- PANK1 | c.597G>T p.P199= | Silent (SNP) | VAF 78/442 reads (18%) | called by muse, mutect2, varscan2
- RAD54B | c.1107T>C p.N369= | Silent (SNP) | VAF 46/318 reads (14%) | called by muse, mutect2, varscan2
- SGSH | c.1395G>A p.R465= | Silent (SNP) | VAF 54/554 reads (10%) | catalogued as rs764491308; called by muse, mutect2
- SLC22A4 | c.519C>G p.L173= | Silent (SNP) | VAF 46/460 reads (10%) | called by muse, mutect2
- SLC26A3 | c.1257C>T p.I419= | Silent (SNP) | VAF 101/597 reads (17%) | catalogued as rs140126824; called by muse, mutect2, varscan2
- SLC45A3 | c.1296G>A p.L432= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs774366329; called by muse, mutect2
- SPATA5L1 | c.990C>T p.D330= | Silent (SNP) | VAF 49/353 reads (14%) | called by muse, mutect2, varscan2
- STAB2 | c.7560G>A p.E2520= | Silent (SNP) | VAF 21/188 reads (11%) | called by muse, mutect2, varscan2
- TERT | c.471G>A p.A157= | Silent (SNP) | VAF 122/1232 reads (10%) | called by muse, mutect2, varscan2
- TMC1 | c.1335C>T p.R445= | Silent (SNP) | VAF 52/348 reads (15%) | called by mutect2, varscan2
- TMEM94 | c.1815C>T p.F605= | Silent (SNP) | VAF 49/306 reads (16%) | called by muse, mutect2, varscan2
- TSPO2 | c.102G>A p.P34= | Silent (SNP) | VAF 44/269 reads (16%) | catalogued as rs755891632; called by muse, mutect2, varscan2
- WASHC5 | c.1575C>T p.A525= | Silent (SNP) | VAF 68/258 reads (26%) | catalogued as rs531094216, COSV100572354, COSV59199455; called by muse, mutect2, varscan2
- XKR6 | c.1398G>A p.P466= | Silent (SNP) | VAF 50/157 reads (32%) | catalogued as rs552864192, COSV58657541; called by muse, mutect2, varscan2
- ZIC2 | c.783C>A p.I261= | Silent (SNP) | VAF 229/818 reads (28%) | called by muse, mutect2, varscan2
- ZNF100 | c.1278G>A p.E426= | Silent (SNP) | VAF 39/280 reads (14%) | called by muse, mutect2, varscan2
- ZNF234 | c.1395C>T p.F465= | Silent (SNP) | VAF 20/170 reads (12%) | catalogued as rs267605533; called by muse, mutect2, varscan2
- ZNF354B | c.144G>A p.R48= | Silent (SNP) | VAF 31/156 reads (20%) | called by muse, mutect2, varscan2
- AC093155.3 | c.767-1269G>T | Intron (SNP) | VAF 42/275 reads (15%) | catalogued as rs530703996; called by muse, mutect2, varscan2
- ADAM21P1 | n.1897C>G | RNA (SNP) | VAF 37/286 reads (13%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+83202G>T | Intron (SNP) | VAF 120/652 reads (18%) | catalogued as rs762573164; called by muse, varscan2
- CHMP1A | c.381+87C>G | Intron (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- CRTC3 | c.578-19C>G | Intron (SNP) | VAF 13/110 reads (12%) | catalogued as COSV51598009; called by muse, mutect2, varscan2
- FCN1 | c.*241G>C | 3'UTR (SNP) | VAF 28/172 reads (16%) | called by muse, mutect2, varscan2
- GDAP1 | c.*1617_*1618dup | 3'UTR (INS) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- GRIN2A | c.1777+29A>T | Intron (SNP) | VAF 44/262 reads (17%) | called by muse, mutect2, varscan2
- HCG27 | n.210C>G | RNA (SNP) | VAF 98/458 reads (21%) | catalogued as rs1452229742; called by muse, mutect2
- IQCN | c.2617-168C>A | Intron (SNP) | VAF 49/262 reads (19%) | called by muse, mutect2, varscan2
- MIRLET7BHG | n.309-3707G>C | Intron (SNP) | VAF 90/469 reads (19%) | called by muse, mutect2, varscan2
- MPC1 | c.76-118A>T | Intron (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- NBPF22P | n.442C>T | RNA (SNP) | VAF 58/568 reads (10%) | called by muse, mutect2
- POM121 | chr7:72948798 C>T | 3'Flank (SNP) | VAF 95/482 reads (20%) | catalogued as rs782092053, COSV57513105; called by muse, mutect2, varscan2
- PON3 | c.202-5330C>A | Intron (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- PRIM1 | c.*84C>A | 3'UTR (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- PTPRT | c.2176+12044G>C | Intron (SNP) | VAF 66/376 reads (18%) | called by muse, mutect2, varscan2
- PTX4 | c.142-385C>T | Intron (SNP) | VAF 62/315 reads (20%) | catalogued as rs199725289; called by muse, mutect2, varscan2
- RGPD1 | c.48+5887C>T | Intron (SNP) | VAF 34/448 reads (8%) | catalogued as rs779290736; called by muse, mutect2
- SDSL | c.-143-1447C>G | Intron (SNP) | VAF 45/326 reads (14%) | called by muse, varscan2
- TALDO1 | c.-10C>G | 5'UTR (SNP) | VAF 111/499 reads (22%) | catalogued as rs769450671; called by muse, varscan2
- ZNF137P | n.1450C>G | RNA (SNP) | VAF 23/150 reads (15%) | called by muse, mutect2, varscan2
- ZNF252P | chr8:145003125 T>A | 5'Flank (SNP) | VAF 46/504 reads (9%) | called by muse, mutect2
- ZNF44 | c.*265C>A | 3'UTR (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
